Somatic mutation profile of tumor specimen TCGA-CR-5250-01A (aliquot TCGA-CR-5250-01A-01D-1512-08) from TCGA case TCGA-CR-5250, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; Tumor grade: G3; Age at diagnosis: 71.4 years (26,097 days).
Specimen TCGA-CR-5250-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed245ff8-d9c7-4ed1-ab7d-a41906abdb4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CR-5250-10A (Blood Derived Normal), aliquot TCGA-CR-5250-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82dfda9f-c111-4d89-91ee-3a162c3c43e5

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 6, Frame Shift Del 2, 3'UTR 1, Translation Start Site 1, Frame Shift Ins 1, Intron 1, RNA 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP2K1 | c.303_308del p.E102_I103del | In Frame Del (DEL) | VAF 19/68 reads (28%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- RAC1 | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 30/89 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.454); catalogued as COSV100640958, COSV61822452, COSV61823434; called by muse, mutect2, varscan2
- ALS2CL | c.858C>G p.H286Q | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100014768; called by muse, mutect2, varscan2
- CACNA1E | c.6248G>A p.R2083Q (on ENST00000367573 / NM_001205293.3; = p.R2040Q on NM_000721.4) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs758936777, COSV100701290, COSV100704942; called by mutect2, varscan2
- CIT | c.4771C>A p.R1591S | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.987); catalogued as COSV99948420, COSV99948538; called by muse, mutect2, varscan2
- CKAP5 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.096); catalogued as COSV100370424; called by muse, mutect2, varscan2
- COL6A2 | c.2200C>T p.R734C | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs886038496, COSV56006569; ClinVar: likely benign; called by muse, varscan2
- DLST | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV99471790; called by muse, mutect2, varscan2
- FNDC3A | c.2740A>G p.I914V (on ENST00000492622 / NM_001079673.2; = p.I858V on NM_014923.5) | Missense Mutation (SNP) | VAF 56/173 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752192574, COSV101256612; called by muse, mutect2, varscan2
- GALNT6 | c.1552G>A p.G518R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs142431103, COSV62541992; called by muse, mutect2, varscan2
- IL3RA | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV100452178; called by mutect2, varscan2
- IPO7 | c.3044G>C p.G1015A | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.338); catalogued as COSV101121784, COSV65684901; called by muse, mutect2, varscan2
- MC3R | c.532G>C p.V178L | Missense Mutation (SNP) | VAF 45/126 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs757261358, COSV99710435; called by muse, mutect2, varscan2
- NCR1 | c.264G>A p.M88I | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs764218143, COSV52558200; called by muse, mutect2, varscan2
- PDE12 | c.1177C>T p.L393F | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as rs750240199, COSV100239695; called by muse, mutect2, varscan2
- PTGES2 | c.595G>A p.G199S | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99476238, COSV99476433; called by muse, mutect2, varscan2
- RASGEF1C | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100745610; called by muse, mutect2, varscan2
- SH2D3C | c.2044A>G p.M682V (on ENST00000314830 / NM_170600.3; = p.M525V on NM_005489.4) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100136415; called by muse, mutect2, varscan2
- SPTBN1 | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs754107495, COSV61691734; called by muse, mutect2
- TENM2 | c.4618G>C p.D1540H (on ENST00000518659 / NM_001122679.2; = p.D1301H on NM_001080428.3) | Missense Mutation (SNP) | VAF 84/256 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV101317858; called by muse, mutect2, varscan2
- THSD7B | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 81/183 reads (44%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.783); catalogued as rs1285881631, COSV99744663; called by muse, mutect2, varscan2
- TRA2B | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 29/76 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); catalogued as COSV60747481; called by muse, mutect2, varscan2
- TRRAP | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs376121665; called by muse, mutect2
- TTN | c.95297A>G p.D31766G (on ENST00000591111; = p.D24342G on NM_003319.4) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | PolyPhen benign (0.443); catalogued as COSV100594890; called by muse, mutect2, varscan2
- UGT2B11 | c.652C>A p.L218I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.151); catalogued as rs755784332, COSV101485217, COSV71424154; called by muse, mutect2, varscan2
- USP35 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.092); catalogued as COSV71572691; called by muse, mutect2, varscan2
- USP9Y | c.2083C>G p.R695G | Missense Mutation (SNP) | VAF 41/54 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100168202; called by muse, mutect2, varscan2
- WIPF1 | c.92C>G p.A31G | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.63); catalogued as COSV99767962; called by muse, mutect2, varscan2
- ZFAND5 | c.143G>A p.S48N | Missense Mutation (SNP) | VAF 71/213 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as COSV99428394; called by muse, mutect2, varscan2
- C1S | c.479dup p.E161Gfs*6 | Frame Shift Ins (INS) | VAF 38/179 reads (21%) | called by mutect2, pindel, varscan2
- CSMD3 | c.7208del p.N2403Mfs*5 (on ENST00000297405 / NM_001363185.1; = p.N2299Mfs*5 on NM_052900.3) | Frame Shift Del (DEL) | VAF 38/108 reads (35%) | called by mutect2, pindel, varscan2
- TRAF3 | c.631del p.Q211Rfs*4 | Frame Shift Del (DEL) | VAF 8/21 reads (38%) | called by mutect2, pindel, varscan2
- TRIM62 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 2/17 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.107); called by muse, mutect2
- CLN6 | c.456C>T p.P152= | Silent (SNP) | VAF 68/210 reads (32%) | catalogued as COSV99992521; called by muse, mutect2, varscan2
- COL1A2 | c.3600C>T p.G1200= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as rs777362679, COSV51955606, COSV99798646; ClinVar: likely benign; called by muse, mutect2, varscan2
- STAB2 | c.4473C>A p.T1491= | Silent (SNP) | VAF 82/249 reads (33%) | catalogued as COSV101185632, COSV66334672; called by muse, mutect2, varscan2
- VGLL4 | c.783C>T p.S261= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV99809206; called by muse, mutect2, varscan2
- XIRP2 | c.8352G>A p.S2784= (on ENST00000628543; = p.S2959= on NM_152381.6) | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as rs917711049, COSV99738679; called by muse, mutect2, varscan2
- ZNF449 | c.1407G>A p.G469= | Silent (SNP) | VAF 90/126 reads (71%) | catalogued as COSV100202805; called by muse, mutect2, varscan2
- ACACB | c.6497-348G>T | Intron (SNP) | VAF 53/212 reads (25%) | catalogued as COSV100622351; called by muse, mutect2, varscan2
- ACAD9 | c.*196G>A | 3'UTR (SNP) | VAF 11/39 reads (28%) | catalogued as COSV100458965; called by muse, mutect2, varscan2
- SNORD116-15 | n.21A>G | RNA (SNP) | VAF 24/185 reads (13%) | called by muse, mutect2, varscan2
